CCDI case PBCNCH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/8802aea0-473a-40e1-b809-3f7ad394af1b

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.1 years (5,879 days).

Biospecimens (2 samples)
- Sample 0DVVL3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVVME: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
